CCDI case PBCTYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/4008242c-67d6-4d6b-9fdc-ab65fd9e8040

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Optic nerve; Age at diagnosis: 9.2 years (3,358 days).

Biospecimens (3 samples)
- Sample 0E0KXE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E0KXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0KY7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
